TCGA case TCGA-13-0765 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/774ce281-96b2-467a-9170-079797ee10f7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 1,389 days (3.8 years).

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,574 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 163 days; Number of cycles: 6; Treatment dose: 75 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 163 days; Number of cycles: 6; Treatment dose: 60 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 163 days; Number of cycles: 6; Treatment dose: 135 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 71 days; Days to treatment end: 155 days; Treatment dose: 15 mg/m2.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 176 days; Days to treatment end: 519 days (1.4 years); Treatment dose: 15 mg/kg.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 589 days (1.6 years); Days to treatment end: 654 days (1.8 years); Treatment dose: 20 mg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 52.7 years (19,242 days); Days to diagnosis: 668 days (1.8 years); Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.7 years (19,242 days); Days to diagnosis: 668 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 668 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 668 days (1.8 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 869 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,389 days (3.8 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-0765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-13-0765-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 99; Percent normal cells: 1; Percent necrosis: 1.
  Slide TCGA-13-0765-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-13-0765-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 5, Route of administrations: Route of administration: IP.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Follow-up form 2: Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,389 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,389 days; disease-free interval: event (new tumor event after initially disease-free), 668 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 668 days.
